Somatic mutation profile of tumor specimen TCGA-CS-6665-01A (aliquot TCGA-CS-6665-01A-11D-1893-08) from TCGA case TCGA-CS-6665, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 52.0 years (18,977 days).
Specimen TCGA-CS-6665-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9d566ba-bb5d-4e84-9118-5d61bdc6261d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6665-10A (Blood Derived Normal), aliquot TCGA-CS-6665-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ca20a87-2932-4578-99d3-a8c47eb68571

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 18, Nonsense Mutation 4, Frame Shift Del 2, 3'Flank 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS18 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as rs762638651, COSV51400387, COSV51421199; called by muse, mutect2, varscan2
- AJAP1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776659293, COSV65453220; called by muse, mutect2, varscan2
- AMMECR1 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53319692; called by muse, mutect2, varscan2
- AP4E1 | c.1952T>G p.L651R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV55919302; called by muse, mutect2, varscan2
- APOA1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV52636624; called by muse, mutect2, varscan2
- BSN | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768423977, COSV56516507; called by muse, mutect2, varscan2
- BSN | c.7625C>T p.T2542M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as rs187902453; called by muse, mutect2, varscan2
- CACNA2D3 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV55569170; called by muse, mutect2, varscan2
- CD244 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV59240599; called by muse, mutect2, varscan2
- CFP | c.425G>T p.W142L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55951139; called by muse, mutect2, varscan2
- CISH | c.661C>T p.R221C (on ENST00000348721 / NM_145071.4; = p.R238C on NM_013324.6) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs771770192, COSV62295380; called by muse, mutect2, varscan2
- CLSTN1 | c.2275T>G p.F759V (on ENST00000377298 / NM_001009566.3; = p.F749V on NM_014944.4) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63650324; called by muse, mutect2, varscan2
- CSHL1 | c.649G>A p.E217K (on ENST00000309894 / NM_022581.3; = p.E123K on NM_001318.4) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV51989483; called by muse, mutect2, varscan2
- DNAJC7 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV57269978; called by muse, mutect2, varscan2
- DOCK5 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs374015497; called by muse, mutect2, varscan2
- EMILIN2 | c.1682del p.P561Lfs*23 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as COSV54426900; called by mutect2, pindel, varscan2
- FAM120C | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.098); catalogued as COSV60261703; called by muse, mutect2, varscan2
- FCGBP | c.9388G>A p.A3130T | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs367948062; called by muse, mutect2, varscan2
- FOXP2 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV63491918; called by muse, mutect2, varscan2
- FRAS1 | c.8192T>G p.F2731C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53636810; called by muse, mutect2, varscan2
- GMDS | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV66413185, COSV66419669; called by muse, mutect2, varscan2
- GPR137B | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 62/238 reads (26%) | catalogued as rs745612968, COSV63991412; called by muse, mutect2, varscan2
- GYG2 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV58551327; called by muse, mutect2, varscan2
- IRAK3 | c.902T>C p.L301S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164557; called by muse, mutect2, varscan2
- KNL1 | c.1732T>C p.S578P (on ENST00000346991 / NM_170589.5; = p.S552P on NM_144508.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV61158977; called by muse, mutect2, varscan2
- LAMA3 | c.7094A>G p.N2365S (on ENST00000313654 / NM_198129.4; = p.N756S on NM_000227.6) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52540756; called by muse, mutect2, varscan2
- MYO16 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1260492120, COSV51781943; called by muse, mutect2, varscan2
- NEXMIF | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50076650; called by muse, mutect2, varscan2
- NT5E | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV57629828; called by muse, mutect2, varscan2
- OR9G1 | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV56453341; called by muse, mutect2, varscan2
- PCSK2 | c.1365G>T p.M455I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52740587; called by muse, mutect2, varscan2
- POLR3D | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV60571998; called by muse, mutect2, varscan2
- PRDM5 | c.1517T>G p.V506G | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV53365456; called by muse, mutect2, varscan2
- PRPS2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.33); catalogued as COSV66180105; called by muse, mutect2, varscan2
- RND3 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV55725630; called by muse, mutect2, varscan2
- RNGTT | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs781242185, COSV55658098; called by muse, mutect2, varscan2
- RS1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.57); catalogued as rs745526075, COSV66107349; called by muse, mutect2, varscan2
- RXRG | c.141T>G p.D47E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV63232843; called by muse, mutect2
- RYR2 | c.7158C>G p.N2386K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV63705926; called by muse, mutect2, varscan2
- SEL1L3 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53547576; called by muse, mutect2, varscan2
- SELE | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60977137; called by muse, mutect2, varscan2
- SELENOF | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV59356682; called by muse, mutect2, varscan2
- SERPINB11 | c.572A>T p.K191I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV66957634; called by muse, mutect2, varscan2
- SHROOM3 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV56026923, COSV99935631; called by muse, mutect2, varscan2
- SPRR2G | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | PolyPhen benign (0); catalogued as rs751390772, COSV64203315; called by muse, mutect2, varscan2
- TMEM200A | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51657691; called by muse, mutect2, varscan2
- TNXB | c.4664C>T p.A1555V (on ENST00000647633; = p.A1308V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs749058728, COSV64476201; called by muse, varscan2
- TP53 | c.833del p.P278Lfs*67 | Frame Shift Del (DEL) | VAF 33/56 reads (59%) | catalogued as CM961376, COSV52661225, COSV52665769, COSV52678063; called by mutect2, pindel, varscan2
- TRAPPC8 | c.3387C>G p.S1129R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51975996, COSV99352160; called by muse, mutect2, varscan2
- USP51 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs759275168, COSV72351875; called by muse, mutect2, varscan2
- USP53 | c.2937T>A p.D979E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV56796856; called by muse, mutect2, varscan2
- WNT2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV55412998; called by muse, mutect2, varscan2
- ZDBF2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1208250066, COSV100984250, COSV65629012; called by muse, mutect2, varscan2
- ZNF479 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100483117, COSV58642366; called by muse, mutect2, varscan2
- ZNF585B | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV57216579; called by muse, mutect2, varscan2
- CYTH4 | c.772_774del p.F258del | In Frame Del (DEL) | VAF 36/106 reads (34%) | called by pindel, varscan2
- ACSM1 | c.1539C>T p.A513= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV54638949; called by muse, mutect2, varscan2
- ADGRF5 | c.2880G>A p.R960= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV51938517; called by muse, mutect2, varscan2
- AKR1B10 | c.42C>T p.P14= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs757140278, COSV62056318; called by muse, mutect2, varscan2
- ATP8A2 | c.2763C>A p.T921= | Silent (SNP) | VAF 60/174 reads (34%) | catalogued as COSV54970585; called by muse, mutect2, varscan2
- CLVS1 | c.906C>T p.S302= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV57980937; called by muse, mutect2, varscan2
- COL5A1 | c.363C>T p.N121= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs369180922; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.1503C>T p.R501= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as rs374548181; called by muse, mutect2, varscan2
- EDEM3 | c.687A>G p.A229= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV58927048; called by muse, mutect2, varscan2
- FAM47B | c.1077C>T p.D359= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs770049861, COSV61453958; called by muse, mutect2, varscan2
- FOLH1 | c.807A>G p.T269= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs752584397, COSV57054717, COSV99923298; called by muse, mutect2, varscan2
- HTR1E | c.375C>A p.T125= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV59510091; called by muse, mutect2, varscan2
- KERA | c.252A>G p.E84= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV57131530; called by muse, mutect2, varscan2
- LGALS3BP | c.1659G>A p.S553= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs777190093, COSV53165272, COSV53166206; called by muse, mutect2, varscan2
- OR5D14 | c.501G>T p.R167= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as COSV59457945; called by muse, mutect2, varscan2
- POLA1 | c.3174G>A p.L1058= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV66889757; called by muse, mutect2, varscan2
- S1PR2 | c.691C>T p.L231= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV58485768; called by muse, mutect2, varscan2
- SP100 | c.1725A>G p.R575= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV50996019; called by muse, mutect2, varscan2
- TMCC3 | c.804C>T p.N268= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs776388594, COSV54151897; called by muse, mutect2, varscan2
- BCL11A | chr2:60452593 C>T | 3'Flank (SNP) | VAF 37/153 reads (24%) | catalogued as rs768802721, COSV59629874; called by muse, mutect2, varscan2
- NRG1 | c.700+606A>T | Intron (SNP) | VAF 38/238 reads (16%) | catalogued as COSV99828311; called by muse, varscan2
